Surgical pathology report (de-identified scan), TCGA case TCGA-21-5786, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-5786-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Clinical History/Diagnosis: Right lung mass.

TCGA-21-5786

Source of Specimen(s):

1: Right upper lobe Lung, wedge biopsy

2: Level 11 Node

3: Right upper lobe Lung, resection (segmental or lobe)

Gross Description:

Received in three parts.

Source of tissue: 1. Labeled #1, wedge right upper lobe"

Intraoperative Consultation: SQUAMOUS CELL CARCINOMA PER [REDACTED]
(VERIFIED).

Gross Description: Received fresh labeled, wedge right upper lobe" consists of a 9 x 4 x 2.5 cm wedge of red-brown lung. The specimen is sectioned revealing a 2.6 x 2.4 x 2.2 cm tan, ill-defined nodule that is approximately 0.5 cm from the resected margin. A piece of the mass is frozen. The remainder of the parenchyma is homogeneous, red-brown and spongy. Representative sections are submitted as designated for microscopic evaluation.

Designation of Sections: 1FS frozen section. 1A shaved margin. 1B random tumor. 1C tumor in relation to normal.

Source of tissue: 2. Labeled #2, level 11R lymph node"

Gross Description: Received fresh labeled, level 11R lymph node" consists of multiple black lymph nodes measuring 2 x 1.5 x 1 cm in aggregate. Entirely submitted in cassette 2A for microscopic evaluation.

Source of tissue: 3. Labeled #3, right upper lobe lung"

Intraoperative Consultation: BRONCHIAL MARGIN WITH NO TUMOR SEEN PER [REDACTED]

Gross Description: Received fresh labeled ", right upper lobe lung" consists of a 131 gram, 11.5 x 8.3 x 3.5 cm red-brown lobe of lung. The bronchial margin is frozen. The specimen is sectioned to reveal a 0.2 x 0.2 x 0.1 cm ill-defined, firm nodule located approximately 6 cm from the bronchial margin. No lymph nodes are grossly identified. No other masses are grossly identified. The remainder of the parenchyma is homogenous red-brown, hemorrhagic and spongy to congested. Representative sections are submitted as designated for microscopic evaluation.

Designation of Sections: 3FS bronchial margin. 3A vessel margins. 3B nodule. 3C normal.

[page 2 of 2]
Final Diagnosis:

1. Lung, right upper lobe, wedge biopsy:

- Squamous cell carcinoma, moderate and poorly differentiated (2.6 cm); tumor invades large vessels; carcinoma invades into and through the visceral pleura.
- Shave of stapled parenchymal margin with no tumor seen.
- Parietal pleural margin with no tumor seen.

2. Level 11 lymph nodes, excision:

- No tumor seen in three lymph nodes, (0/3).

TCGA - 21 - 5786

3. Lung, right upper lobe, lobectomy:

- Emphysema and focal interstitial fibrosis.
- Bronchial and vascular margins with no tumor seen.

LUNG TEMPLATE

Specimen Type
Lobectomy

Laterality
Right

Tumor Site
Upper lobe

Tumor Size
Greatest dimension: 2.6 cm (T1 if ≤ 3.0 cm; otherwise T2)

Histologic Type
Squamous cell carcinoma

Histologic Grade
Poorly differentiated

Extension of Tumor
Carcinoma invades into/through visceral pleura (T2)

Venous (Large Vessel) Invasion
Present

Arterial (Large Vessel) Invasion
Present

Margins: Margins uninvolved by invasive carcinoma

Regional Lymph Nodes
3 regional lymph nodes examined
No regional lymph node metastasis

pTNM: T2 No Mx

Source: NCI Genomic Data Commons file b74c8053-b832-4045-8afd-dc367c77358e (TCGA-21-5786.7C63D47F-0A73-415C-B4E5-D5C70886709E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).